Somatic mutation profile of tumor specimen BA2456D (aliquot aq-BA2456D) from BEATAML1.0 case 2481, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.8 years (24,048 days).
Specimen BA2456D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c088f87b-3ca4-44a5-b725-6f49e3b44531.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2863D (Solid Tissue Normal), aliquot aq-BA2863D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/564edd77-bc49-4d12-b40c-a2e164655aec

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 5, Silent 3, Nonsense Mutation 2, RNA 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ADH5 | c.344+1G>A p.X115_splice | Splice Site (SNP) | VAF 59/194 reads (30%) | catalogued as rs770825524; called by muse, mutect2, varscan2
- EPHA3 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756739935, COSV60693553; called by muse, mutect2, varscan2
- FLT3 | c.1775T>G p.V592G | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54051432, COSV54058572, COSV54074139; called by muse, mutect2
- NPM1 | c.863_864insCAGG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by mutect2, pindel, varscan2
- RIMS1 | c.3391C>T p.R1131* | Nonsense Mutation (SNP) | VAF 63/188 reads (34%) | catalogued as COSV99326707; called by muse, mutect2, varscan2
- DSCAM | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ECD | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); called by muse, mutect2
- GIT2 | c.1904C>T p.P635L (on ENST00000355312 / NM_057169.5; = p.P557L on NM_014776.5) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- NDUFS4 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- NNT | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- SCN10A | c.3817G>T p.A1273S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPH2 | c.843C>A p.Y281* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- UBTF | c.2141G>T p.S714I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.118); called by muse, mutect2
- ZDHHC14 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- C4BPB | c.648C>T p.C216= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs145016760; called by muse, mutect2, varscan2
- KIR3DL3 | c.1179A>G p.K393= | Silent (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- RAI1 | c.840G>A p.Q280= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs398124421, COSV55389171, COSV55391242, COSV55397452; ClinVar: benign; called by muse, varscan2
- AC092118.1 | n.1157C>A | RNA (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- CDH3 | c.46-48C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- CELF2 | c.1075+135A>G | Intron (SNP) | VAF 19/68 reads (28%) | catalogued as rs960797706; called by muse, mutect2, varscan2
- CFH | c.2957-18A>G | Intron (SNP) | VAF 45/137 reads (33%) | catalogued as rs957390889; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86016C>T | Intron (SNP) | VAF 35/120 reads (29%) | catalogued as rs1233255479, COSV72277403; called by muse, mutect2, varscan2
- NEB | c.8890-3082A>T | Intron (SNP) | VAF 8/47 reads (17%) | called by mutect2, varscan2
- SSPOP | n.15750C>A | RNA (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
